Somatic mutation profile of tumor specimen TARGET-30-PALJPX-01A (aliquot TARGET-30-PALJPX-01A-01W) from TARGET case TARGET-30-PALJPX, project TARGET-NBL (Neuroblastoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Abdomen, NOS; Age at diagnosis: 2.4 years (860 days).
Specimen TARGET-30-PALJPX-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 85ffd8a3-4b20-473d-901c-123de5555591.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PALJPX-10A (Blood Derived Normal), aliquot TARGET-30-PALJPX-10A-01W; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5f39d58c-7032-4957-908b-cc0ac8949a7f

The open-access MAF lists 125 somatic variants for this specimen: 96 protein-altering or splice-affecting, 23 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 79, Silent 23, Nonsense Mutation 16, RNA 3, Intron 2, Splice Site 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA13 | c.6246G>T p.M2082I | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV70037031; called by muse, mutect2, varscan2
- ABCC4 | c.3802C>A p.L1268I | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT tolerated (0.21); PolyPhen benign (0.066); catalogued as COSV65315945; called by muse, mutect2, varscan2
- AKR1C3 | c.509G>T p.R170L | Missense Mutation (SNP) | VAF 33/153 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.208); catalogued as rs782156465, COSV65910858; called by muse, mutect2, varscan2
- AP1G1 | c.1784C>A p.P595H | Missense Mutation (SNP) | VAF 63/271 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.025); catalogued as COSV55492838; called by muse, mutect2, varscan2
- BICRAL | c.1162C>A p.H388N | Missense Mutation (SNP) | VAF 23/581 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV104403612, COSV58405723; called by muse, mutect2
- C6 | c.563C>A p.P188H | Missense Mutation (SNP) | VAF 24/379 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54704266; called by muse, mutect2
- CABYR | c.92C>A p.S31* | Nonsense Mutation (SNP) | VAF 17/59 reads (29%) | catalogued as COSV59111960, COSV59112058; called by muse, mutect2, varscan2
- CCM2 | c.190G>T p.E64* | Nonsense Mutation (SNP) | VAF 9/209 reads (4%) | catalogued as COSV51850710; called by muse, mutect2
- CDH23 | c.655C>A p.L219M | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV54933439, COSV54937014; called by muse, mutect2
- COG5 | c.860C>T p.P287L | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.973); catalogued as COSV51758033; called by muse, mutect2, varscan2
- COL4A1 | c.2036G>T p.G679V | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65428188; called by muse, mutect2, varscan2
- CORO2B | c.1088C>A p.S363Y | Missense Mutation (SNP) | VAF 9/190 reads (5%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.506); catalogued as COSV99963215; called by muse, mutect2
- CPS1 | c.1356G>T p.M452I | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.076); catalogued as COSV51817813; called by muse, mutect2, varscan2
- CTSZ | c.658G>T p.E220* | Nonsense Mutation (SNP) | VAF 6/82 reads (7%) | catalogued as COSV53882976; called by muse, mutect2
- CTTNBP2 | c.3617C>A p.S1206* | Nonsense Mutation (SNP) | VAF 22/38 reads (58%) | catalogued as COSV50389357, COSV50430448; called by muse, varscan2
- DCTN1 | c.1678G>T p.A560S | Missense Mutation (SNP) | VAF 31/72 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV100720993, COSV62621022; called by muse, mutect2, varscan2
- DDB1 | c.2175C>A p.C725* | Nonsense Mutation (SNP) | VAF 50/120 reads (42%) | catalogued as COSV57104183; called by muse, mutect2, varscan2
- DHPS | c.611C>A p.S204Y | Missense Mutation (SNP) | VAF 31/309 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV52952735; called by muse, mutect2
- DIO1 | c.556C>A p.L186I | Missense Mutation (SNP) | VAF 56/292 reads (19%) | SIFT tolerated (0.46); PolyPhen benign (0.077); catalogued as COSV59518462; called by muse, mutect2, varscan2
- DOCK8 | c.6123A>T p.E2041D | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.524); catalogued as COSV66622289; called by muse, mutect2, varscan2
- EPC1 | c.1627G>T p.E543* | Nonsense Mutation (SNP) | VAF 11/83 reads (13%) | catalogued as COSV53928059; called by muse, mutect2, varscan2
- FBXO4 | c.639G>T p.Q213H | Missense Mutation (SNP) | VAF 8/193 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs1348444647; called by muse, mutect2
- FRAS1 | c.8944C>A p.L2982I | Missense Mutation (SNP) | VAF 7/118 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.93); catalogued as COSV53598210, COSV53625995; called by muse, mutect2
- GPR32 | c.871C>A p.H291N | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT tolerated (0.22); PolyPhen benign (0.055); catalogued as COSV54515112; called by muse, mutect2, varscan2
- HDAC4 | c.2750C>T p.P917L | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1559366304, COSV61871257; called by muse, mutect2, varscan2
- HEATR5B | c.2953C>A p.L985M | Missense Mutation (SNP) | VAF 43/85 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV51856027; called by muse, mutect2, varscan2
- HRH4 | c.707G>T p.R236I | Missense Mutation (SNP) | VAF 11/195 reads (6%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as COSV56928904; called by muse, mutect2
- ICE1 | c.4847G>T p.C1616F | Missense Mutation (SNP) | VAF 14/148 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.948); catalogued as rs755010302, COSV56829031; called by muse, mutect2
- LMBRD2 | c.822+1G>T p.X274_splice | Splice Site (SNP) | VAF 6/28 reads (21%) | catalogued as COSV56951400; called by muse, mutect2, varscan2
- MMS19 | c.2564C>A p.A855D | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV59136522; called by muse, mutect2, varscan2
- MPV17L2 | c.203T>C p.V68A | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.062); catalogued as COSV55853290; called by muse, mutect2
- MTBP | c.1187G>T p.G396V | Missense Mutation (SNP) | VAF 15/125 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59964717; called by muse, mutect2, varscan2
- MTRR | c.436G>T p.G146* (on ENST00000264668; = p.G119* on NM_002454.3 and 4 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 24/360 reads (7%) | catalogued as COSV52947195; called by muse, mutect2
- MYO7B | c.3095G>C p.R1032T | Missense Mutation (SNP) | VAF 71/80 reads (89%) | SIFT tolerated (0.69); PolyPhen benign (0.003); catalogued as COSV67349671; called by muse, mutect2, varscan2
- NBPF1 | c.1939G>T p.E647* | Nonsense Mutation (SNP) | VAF 48/565 reads (8%) | catalogued as COSV55327415; called by muse, varscan2
- NEIL1 | c.1139C>A p.P380Q | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.001); catalogued as rs775205005, COSV51233737; called by muse, mutect2, varscan2
- NF1 | c.7501G>T p.E2501* (on ENST00000358273 / NM_001042492.3; = p.E2480* on NM_000267.3) | Nonsense Mutation (SNP) | VAF 6/44 reads (14%) | catalogued as COSV62209962, COSV62214761; called by mutect2, varscan2
- NOL8 | c.2032G>T p.G678C | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.013); catalogued as COSV62636499; called by muse, mutect2, varscan2
- OBSCN | c.9619G>A p.V3207M | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.16); catalogued as rs1013031418, COSV52802132; called by muse, mutect2, varscan2
- OR2M7 | c.684G>T p.M228I | Missense Mutation (SNP) | VAF 89/772 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.068); catalogued as COSV58738609; called by muse, mutect2, varscan2
- PCDH9 | c.1252C>A p.Q418K | Missense Mutation (SNP) | VAF 16/81 reads (20%) | SIFT tolerated (0.66); PolyPhen probably damaging (0.998); catalogued as COSV60572099; called by muse, mutect2, varscan2
- PCDHB9 | c.1069G>T p.A357S | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.287); catalogued as COSV53381525; called by muse, mutect2, varscan2
- PCDHB9 | c.1987G>T p.V663L | Missense Mutation (SNP) | VAF 17/129 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.437); catalogued as COSV53381530; called by muse, mutect2, varscan2
- PCNX2 | c.5476G>T p.G1826W | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs773468709, COSV50838361; called by muse, mutect2, varscan2
- PHF11 | c.143G>T p.C48F | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62896787; called by muse, mutect2, varscan2
- PKDREJ | c.3757C>A p.Q1253K | Missense Mutation (SNP) | VAF 16/119 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.872); catalogued as COSV53551128; called by muse, mutect2, varscan2
- PLAUR | c.889G>T p.D297Y | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT tolerated (0.43); PolyPhen benign (0.025); catalogued as rs1340337831, COSV55390789; called by muse, mutect2, varscan2
- PRAMEF12 | c.1297G>T p.G433W | Missense Mutation (SNP) | VAF 19/95 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.977); catalogued as COSV63216033; called by muse, mutect2, varscan2
- PRDM9 | c.209G>T p.R70L | Missense Mutation (SNP) | VAF 44/100 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.353); catalogued as rs767394233, COSV57005322, COSV57010207; called by muse, mutect2, varscan2
- PYGM | c.2301G>A p.M767I | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT deleterious (0.05); PolyPhen benign (0.005); catalogued as COSV51222465; called by muse, mutect2, varscan2
- RAPGEF6 | c.741G>T p.Q247H | Missense Mutation (SNP) | VAF 37/97 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV57251092; called by muse, mutect2, varscan2
- SLC11A1 | c.898C>A p.L300I | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT tolerated (0.27); PolyPhen benign (0.268); catalogued as COSV51918353; called by muse, mutect2, varscan2
- SMAD4 | c.1013C>A p.T338K | Missense Mutation (SNP) | VAF 32/180 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.943); catalogued as COSV100748289, COSV61690649; called by muse, varscan2
- SMC1B | c.389C>A p.A130E | Missense Mutation (SNP) | VAF 14/152 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.795); catalogued as COSV100662867; called by muse, mutect2
- STAG3 | c.349G>T p.E117* | Nonsense Mutation (SNP) | VAF 20/302 reads (7%) | catalogued as COSV57931296; called by muse, mutect2
- TCL1B | c.382G>T p.D128Y | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.06); catalogued as COSV61552170; called by muse, mutect2, varscan2
- TPO | c.778C>A p.Q260K | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT tolerated (0.21); PolyPhen benign (0.114); catalogued as COSV61106561; called by muse, mutect2, varscan2
- TRPM6 | c.3890G>T p.R1297M | Missense Mutation (SNP) | VAF 10/202 reads (5%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.227); catalogued as COSV62507013, COSV62510751; called by muse, mutect2
- TRPM6 | c.1371G>T p.K457N | Missense Mutation (SNP) | VAF 24/110 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62517160; called by muse, mutect2, varscan2
- TSPAN1 | c.360G>T p.L120F | Missense Mutation (SNP) | VAF 20/212 reads (9%) | SIFT tolerated (0.05); PolyPhen benign (0.015); catalogued as COSV64339765; called by muse, mutect2
- TSPEAR | c.1180G>T p.D394Y | Missense Mutation (SNP) | VAF 11/134 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.663); catalogued as COSV59959010; called by muse, mutect2
- UGT1A6 | c.532C>A p.L178M | Missense Mutation (SNP) | VAF 49/312 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.378); catalogued as COSV59394152; called by muse, mutect2, varscan2
- USH2A | c.4900C>A p.L1634M | Missense Mutation (SNP) | VAF 9/167 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.601); catalogued as COSV100232555; called by muse, mutect2
- VPS13C | c.4099C>A p.L1367I (on ENST00000644861 / NM_020821.3; = p.L1324I on NM_017684.5) | Missense Mutation (SNP) | VAF 23/149 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV51337708; called by muse, mutect2, varscan2
- WDR89 | c.847C>A p.H283N | Missense Mutation (SNP) | VAF 18/361 reads (5%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.601); catalogued as COSV50828271; called by muse, mutect2
- ZNF292 | c.2863G>T p.E955* | Nonsense Mutation (SNP) | VAF 53/233 reads (23%) | catalogued as COSV60543341; called by muse, mutect2, varscan2
- ZNF564 | c.145G>T p.D49Y | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.764); catalogued as COSV59435870; called by muse, mutect2, varscan2
- ZNF821 | c.386G>T p.S129I (on ENST00000425432 / NM_001376297.1; = p.S87I on NM_017530.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 23/133 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.348); catalogued as COSV57987969; called by muse, mutect2, varscan2
- ANXA7 | c.1294G>T p.A432S (on ENST00000372919 / NM_001320880.2; = p.A410S on NM_001156.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/152 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.653); called by muse, mutect2
- ARGLU1 | c.460G>T p.E154* | Nonsense Mutation (SNP) | VAF 12/334 reads (4%) | called by muse, mutect2
- ARHGAP31 | c.3593G>T p.R1198M | Missense Mutation (SNP) | VAF 16/300 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); called by muse, mutect2
- CBX5 | c.445G>T p.D149Y | Missense Mutation (SNP) | VAF 6/106 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); called by muse, mutect2
- CTIF | c.672G>T p.Q224H | Missense Mutation (SNP) | VAF 6/61 reads (10%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.747); called by muse, mutect2, varscan2
- CYFIP1 | c.2296C>A p.R766S | Missense Mutation (SNP) | VAF 3/51 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.258); called by muse, mutect2
- EPC1 | c.2383G>T p.A795S | Missense Mutation (SNP) | VAF 10/158 reads (6%) | SIFT tolerated (0.31); PolyPhen benign (0.012); called by muse, mutect2
- HMCN1 | c.12619G>T p.V4207F | Missense Mutation (SNP) | VAF 10/192 reads (5%) | SIFT tolerated (0.43); PolyPhen probably damaging (0.997); called by muse, mutect2
- KLHL24 | c.1046C>A p.P349Q | Missense Mutation (SNP) | VAF 10/138 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2
- KMT2D | c.5306C>A p.P1769H | Missense Mutation (SNP) | VAF 11/133 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- PCDHA1 | c.25C>A p.L9M | Missense Mutation (SNP) | VAF 7/99 reads (7%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.125); called by muse, mutect2
- PCK2 | c.373G>T p.G125C | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.787); called by muse, varscan2
- PCNT | c.9931G>T p.E3311* | Nonsense Mutation (SNP) | VAF 8/94 reads (9%) | called by muse, mutect2
- PCSK5 | c.4604G>T p.C1535F | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- PLXNA4 | c.3460G>T p.E1154* | Nonsense Mutation (SNP) | VAF 20/236 reads (8%) | called by muse, mutect2
- PTCHD3 | c.1321G>T p.V441F | Missense Mutation (SNP) | VAF 6/115 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- RARS1 | c.1468G>T p.E490* | Nonsense Mutation (SNP) | VAF 8/162 reads (5%) | called by muse, mutect2
- RNF157 | c.1663C>A p.Q555K | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by mutect2, varscan2
- SDC1 | c.595C>A p.Q199K | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.391); called by muse, mutect2, varscan2
- SEC14L4 | c.225G>T p.Q75H | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT tolerated (0.05); PolyPhen benign (0.003); called by muse, mutect2
- TBRG4 | c.855G>T p.Q285H | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- TMC5 | c.412G>T p.A138S | Missense Mutation (SNP) | VAF 25/318 reads (8%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.003); called by muse, mutect2
- TTBK2 | c.1882G>T p.A628S | Missense Mutation (SNP) | VAF 16/241 reads (7%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.014); called by muse, mutect2
- TXNDC11 | c.2446C>A p.L816I (on ENST00000356957 / NM_001303447.2; = p.L789I on NM_015914.7 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 5/73 reads (7%) | SIFT tolerated (0.38); PolyPhen benign (0.007); called by muse, mutect2
- YAP1 | c.610A>C p.K204Q | Missense Mutation (SNP) | VAF 16/242 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.791); called by muse, mutect2
- ZNF17 | c.1000G>T p.E334* | Nonsense Mutation (SNP) | VAF 11/195 reads (6%) | called by muse, mutect2
- ZNF417 | c.623G>T p.G208V | Missense Mutation (SNP) | VAF 13/124 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.437); called by mutect2, varscan2
- ZNF426 | c.1167G>T p.E389D | Missense Mutation (SNP) | VAF 6/83 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.646); called by muse, mutect2
- ADAM19 | c.1890C>A p.T630= | Silent (SNP) | VAF 26/240 reads (11%) | catalogued as COSV57434876; called by muse, mutect2, varscan2
- ANKRD35 | c.633C>T p.D211= | Silent (SNP) | VAF 6/80 reads (8%) | catalogued as rs371021116; called by muse, mutect2
- CABCOCO1 | c.387C>A p.P129= | Silent (SNP) | VAF 6/42 reads (14%) | catalogued as COSV57594366, COSV57595931; called by muse, mutect2, varscan2
- CCDC157 | c.1827C>A p.I609= | Silent (SNP) | VAF 7/20 reads (35%) | called by muse, mutect2, varscan2
- CYP20A1 | c.753T>A p.I251= | Silent (SNP) | VAF 30/56 reads (54%) | catalogued as COSV61909974; called by muse, mutect2, varscan2
- DDB2 | c.936C>A p.I312= | Silent (SNP) | VAF 12/136 reads (9%) | catalogued as COSV57039911; called by muse, varscan2
- GMPPB | c.747C>A p.G249= | Silent (SNP) | VAF 17/53 reads (32%) | catalogued as COSV57539436; called by muse, mutect2, varscan2
- GTPBP3 | c.876C>A p.V292= | Silent (SNP) | VAF 11/53 reads (21%) | catalogued as COSV50190236; called by mutect2, varscan2
- HJV | c.1113C>A p.P371= (on ENST00000336751 / NM_213653.4; = p.P258= on NM_145277.5) | Silent (SNP) | VAF 5/31 reads (16%) | catalogued as COSV60952755; called by muse, mutect2, varscan2
- LDLR | c.516C>T p.D172= | Silent (SNP) | VAF 26/52 reads (50%) | catalogued as CM103809, COSV52944814; called by muse, mutect2, varscan2
- MMP1 | c.258G>T p.V86= | Silent (SNP) | VAF 6/113 reads (5%) | called by muse, mutect2
- NCF2 | c.1452C>A p.I484= | Silent (SNP) | VAF 12/163 reads (7%) | called by muse, mutect2
- NMUR1 | c.384G>T p.L128= | Silent (SNP) | VAF 10/87 reads (11%) | catalogued as COSV59405039; called by muse, mutect2, varscan2
- OR4L1 | c.405C>A p.I135= | Silent (SNP) | VAF 31/184 reads (17%) | catalogued as COSV59850662; called by muse, mutect2, varscan2
- PDE7A | c.1377G>T p.S459= (on ENST00000401827 / NM_001242318.3; = p.S433= on NM_002603.4) | Silent (SNP) | VAF 21/137 reads (15%) | catalogued as COSV65153982; called by muse, mutect2, varscan2
- PLEKHG3 | c.2148G>T p.G716= (on ENST00000394691; = p.G772= on NM_001308147.2) | Silent (SNP) | VAF 5/31 reads (16%) | catalogued as rs776749730, COSV55981821; called by mutect2, varscan2
- PUS10 | c.1428C>A p.L476= | Silent (SNP) | VAF 31/245 reads (13%) | catalogued as COSV57453740; called by muse, mutect2, varscan2
- RELN | c.411C>A p.P137= | Silent (SNP) | VAF 43/220 reads (20%) | catalogued as COSV59020694; called by muse, mutect2, varscan2
- SEMA4F | c.1174C>A p.R392= | Silent (SNP) | VAF 6/94 reads (6%) | catalogued as rs1363385772, COSV60282140; called by muse, mutect2
- TENM2 | c.1020C>A p.T340= (on ENST00000518659 / NM_001122679.2; = p.T149= on NM_001080428.3) | Silent (SNP) | VAF 22/215 reads (10%) | called by muse, mutect2
- TESK1 | c.954G>T p.L318= | Silent (SNP) | VAF 10/68 reads (15%) | catalogued as COSV52411862; called by muse, mutect2, varscan2
- TRAFD1 | c.1357C>A p.R453= | Silent (SNP) | VAF 14/106 reads (13%) | catalogued as COSV57503863, COSV57505374; called by muse, mutect2, varscan2
- ZNF446 | c.1131G>T p.G377= | Silent (SNP) | VAF 10/25 reads (40%) | catalogued as COSV59991936; called by muse, mutect2, varscan2
- ARMC5 | c.1864+56C>A | Intron (SNP) | VAF 6/18 reads (33%) | called by muse, mutect2
- DCHS2 | n.4054C>A | RNA (SNP) | VAF 12/135 reads (9%) | called by muse, mutect2
- FBXL21P | n.1313G>T | RNA (SNP) | VAF 24/100 reads (24%) | catalogued as COSV51809671; called by muse, mutect2, varscan2
- MFRP | chr11:119345812 C>A | 5'Flank (SNP) | VAF 8/21 reads (38%) | catalogued as rs372413718; called by muse, varscan2
- PPHLN1 | c.1024+18G>T | Intron (SNP) | VAF 8/77 reads (10%) | called by muse, mutect2, varscan2
- XIST | n.7259C>A | RNA (SNP) | VAF 6/101 reads (6%) | catalogued as rs1186985957; called by muse, mutect2
